MMRF case MMRF_2183 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/4750c9d8-fbf2-45e9-b4b1-89fc82942ad0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 79 years; Vital status: Dead; Days to death: 603 days (1.7 years).

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 79.6 years (29,061 days); Days to last known disease status: 603 days (1.7 years); Days to last follow up: 603 days (1.7 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 103 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days; Days to treatment end: 103 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 121 days; Days to treatment end: 336 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 603.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7 (ECOG 2): M Protein 1.76 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 38.5 mg/dL; Immunoglobulin G 21.4 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.32 g/L; Hemoglobin 6.14 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 6.18 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 3.43 mmol/L; Albumin 33 g/L; Total Protein 9.5 g/dL; Glucose 6.22 mmol/L.
- Day 112 (ECOG 1): M Protein 0.76 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.89 mg/dL; Immunoglobulin G 11.9 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.69 g/L; Hemoglobin 6.26 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 7.96 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 34 g/L; Total Protein 6.7 g/dL; Glucose 5.83 mmol/L.
- Day 175 (ECOG 1): M Protein 0.43 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 11.2 mg/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 1.69 g/L; Immunoglobulin M 0.89 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.46 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 7.5 g/dL; Glucose 5.34 mmol/L.
- Day 260: M Protein 1.02 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 13.5 mg/dL; Immunoglobulin G 15.8 g/L; Immunoglobulin A 1.43 g/L; Immunoglobulin M 1.11 g/L; Hemoglobin 6.7 mmol/L; Leukocytes 9.9 ×10⁹/L; Absolute Neutrophil 8.18 ×10⁹/L; Platelets 295 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 7.7 g/dL; Glucose 7.32 mmol/L.
- Day 344: M Protein 0.63 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 23.9 mg/dL; Immunoglobulin G 13.1 g/L; Immunoglobulin A 1.71 g/L; Immunoglobulin M 1.09 g/L; Hemoglobin 6.7 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.12 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.45 mmol/L; Albumin 40 g/L; Total Protein 7.1 g/dL; Glucose 6.71 mmol/L.

Other clinical attributes
- Day -7: Weight: 58 kg; Height: 165 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2183_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_2183_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
